Somatic mutation profile of tumor specimen TCGA-HE-7130-01A (aliquot TCGA-HE-7130-01A-11D-1961-08) from TCGA case TCGA-HE-7130, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III.
Specimen TCGA-HE-7130-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0dda67d7-92b1-4e52-826e-9705546d4e9d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-HE-7130-10A (Blood Derived Normal), aliquot TCGA-HE-7130-10A-01D-1962-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/288cfc31-f2ce-49a7-aa44-60858f863941

The open-access MAF lists 185 somatic variants for this specimen: 145 protein-altering or splice-affecting, 36 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 126, Silent 36, Nonsense Mutation 11, Frame Shift Del 5, 3'UTR 3, In Frame Del 1, Frame Shift Ins 1, 3'Flank 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BBS2 | c.2107C>T p.R703* | Nonsense Mutation (SNP) | VAF 18/72 reads (25%) | catalogued as rs567573386, CM114528, COSV55325564; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*174A>G | 3'UTR (SNP) | VAF 153/180 reads (85%) | catalogued as rs121913485, CM960657, COSV53390174; ClinVar: likely pathogenic / uncertain significance / pathogenic; called by muse, mutect2, varscan2
- FGFR3 | c.*1006G>C | 3'UTR (SNP) | VAF 15/16 reads (94%) | catalogued as rs28928868, CM002965, CM002966, COSV53395856, COSV53408403; ClinVar: pathogenic; called by muse, varscan2
- KDM6A | c.385-1G>C p.X129_splice | Splice Site (SNP) | VAF 28/61 reads (46%) | hotspot (GDC flag); catalogued as COSV100938553, COSV65038249; called by muse, mutect2, varscan2
- AARS1 | c.8C>G p.S3C | Missense Mutation (SNP) | VAF 68/124 reads (55%) | SIFT deleterious (0); PolyPhen benign (0.285); catalogued as rs946227383, COSV55746568; called by muse, mutect2, varscan2
- ACTR2 | c.886G>A p.E296K | Missense Mutation (SNP) | VAF 63/165 reads (38%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV53199922; called by muse, mutect2, varscan2
- ADGRB1 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 26/68 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs887675747, COSV60093530; called by muse, mutect2, varscan2
- AFDN | c.3494A>C p.K1165T | Missense Mutation (SNP) | VAF 51/65 reads (78%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.263); catalogued as COSV60040118; called by muse, mutect2, varscan2
- AKT2 | c.1285C>G p.Q429E | Missense Mutation (SNP) | VAF 31/68 reads (46%) | SIFT tolerated (0.17); PolyPhen benign (0.021); catalogued as COSV100251435, COSV60907962; called by muse, mutect2, varscan2
- AL592490.1 | c.1766G>A p.G589E | Missense Mutation (SNP) | VAF 21/109 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV69425012; called by muse, mutect2, varscan2
- AL592490.1 | c.1765G>A p.G589R | Missense Mutation (SNP) | VAF 22/110 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101308159, COSV69425240; called by muse, mutect2, varscan2
- AMDHD1 | c.754G>C p.D252H | Missense Mutation (SNP) | VAF 61/160 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.549); catalogued as COSV57137894, COSV57138028; called by muse, mutect2, varscan2
- ANK3 | c.9950C>G p.S3317* | Nonsense Mutation (SNP) | VAF 39/145 reads (27%) | catalogued as COSV55049105; called by muse, mutect2, varscan2
- ANKRD30A | c.1927G>A p.E643K (on ENST00000611781; = p.E587K on NM_052997.2) | Missense Mutation (SNP) | VAF 47/221 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs376283553; called by muse, mutect2, varscan2
- ATP8B3 | c.59C>A p.P20H | Missense Mutation (SNP) | VAF 10/28 reads (36%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV99402509; called by mutect2, varscan2
- BIRC6 | c.1306C>T p.Q436* | Nonsense Mutation (SNP) | VAF 32/90 reads (36%) | catalogued as COSV70196964; called by mutect2, varscan2
- C19orf47 | c.641A>G p.N214S | Missense Mutation (SNP) | VAF 22/49 reads (45%) | SIFT tolerated (0.21); PolyPhen benign (0.165); catalogued as COSV63508654; called by muse, varscan2
- CALHM1 | c.911C>T p.T304M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as rs1196749897, COSV53294683; called by muse, mutect2, varscan2
- CAPN13 | c.947C>T p.S316L | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1316584552, COSV54429306; called by muse, mutect2, varscan2
- CAPRIN2 | c.37G>C p.E13Q | Missense Mutation (SNP) | VAF 14/156 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.067); catalogued as COSV51831414, COSV51832203; called by muse, mutect2
- CASP9 | c.398C>T p.S133F | Missense Mutation (SNP) | VAF 34/191 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as COSV61601067; called by muse, mutect2, varscan2
- CCDC18 | c.2901G>C p.L967F (on ENST00000343253 / NM_001306076.1; = p.L968F on NM_206886.4) | Missense Mutation (SNP) | VAF 8/47 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58141903; called by muse, mutect2, varscan2
- CCDC39 | c.2005C>G p.Q669E | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.945); catalogued as rs751147958, COSV56480494; called by muse, mutect2
- CCDC80 | c.2821C>T p.H941Y | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.031); catalogued as COSV52815598; called by muse, mutect2, varscan2
- CDHR1 | c.250G>A p.D84N | Missense Mutation (SNP) | VAF 60/99 reads (61%) | SIFT tolerated (0.12); PolyPhen benign (0.186); catalogued as rs1435061412, COSV60560534; called by muse, mutect2, varscan2
- CFAP46 | c.6766G>A p.E2256K | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.42); PolyPhen benign (0.068); catalogued as COSV54150261; called by muse, varscan2
- CHD6 | c.4955C>T p.S1652L | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.003); catalogued as COSV64689001; called by muse, mutect2, varscan2
- CHRNB2 | c.812C>A p.S271* | Nonsense Mutation (SNP) | VAF 146/253 reads (58%) | catalogued as COSV63807857; called by muse, mutect2, varscan2
- CLEC4F | c.988G>A p.E330K | Missense Mutation (SNP) | VAF 10/128 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.034); catalogued as COSV55478604; called by muse, mutect2
- CMTM2 | c.413G>C p.R138T | Missense Mutation (SNP) | VAF 7/103 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV51748212; called by muse, mutect2
- CMYA5 | c.2765C>T p.S922F | Missense Mutation (SNP) | VAF 46/87 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.621); catalogued as COSV71404586; called by muse, mutect2, varscan2
- CMYA5 | c.6749G>A p.R2250K | Missense Mutation (SNP) | VAF 69/125 reads (55%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.005); catalogued as COSV71404592; called by muse, mutect2, varscan2
- CMYA5 | c.7294G>C p.E2432Q | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.738); catalogued as COSV71404061, COSV71404594; called by muse, mutect2, varscan2
- CMYA5 | c.7991G>A p.R2664K | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.046); catalogued as COSV71404595; called by muse, mutect2, varscan2
- COL1A2 | c.523G>A p.G175S | Missense Mutation (SNP) | VAF 51/237 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51954917; called by muse, mutect2, varscan2
- COPB1 | c.1352C>G p.S451C | Missense Mutation (SNP) | VAF 68/92 reads (74%) | SIFT deleterious (0); PolyPhen possibly damaging (0.869); catalogued as COSV51447296; called by muse, mutect2, varscan2
- CREBZF | c.236C>T p.S79F | Missense Mutation (SNP) | VAF 35/70 reads (50%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.205); catalogued as rs954684507, COSV52629119; called by muse, mutect2, varscan2
- DDX20 | c.2125G>A p.E709K | Missense Mutation (SNP) | VAF 35/111 reads (32%) | SIFT tolerated (0.39); PolyPhen benign (0.015); catalogued as COSV63778220; called by muse, mutect2, varscan2
- DDX20 | c.2269G>A p.D757N | Missense Mutation (SNP) | VAF 36/121 reads (30%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.018); catalogued as rs1486355426, COSV63778222; called by muse, mutect2, varscan2
- DDX23 | c.514G>A p.E172K | Missense Mutation (SNP) | VAF 84/211 reads (40%) | SIFT tolerated (0.89); PolyPhen benign (0.175); catalogued as COSV57282492; called by muse, mutect2, varscan2
- DDX31 | c.22C>G p.Q8E | Missense Mutation (SNP) | VAF 14/21 reads (67%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV60134708; called by muse, mutect2, varscan2
- DIP2A | c.3922G>A p.V1308I | Missense Mutation (SNP) | VAF 6/18 reads (33%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.938); catalogued as rs761968169, COSV59474399; called by mutect2, varscan2
- DMXL2 | c.5744C>T p.S1915F | Missense Mutation (SNP) | VAF 83/168 reads (49%) | SIFT deleterious (0.04); PolyPhen benign (0.001); catalogued as COSV51842511; called by muse, mutect2, varscan2
- DPY19L2 | c.235C>T p.L79F | Missense Mutation (SNP) | VAF 21/118 reads (18%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.11); catalogued as rs1178324841, COSV60542034; called by muse, mutect2, varscan2
- EBF2 | c.530C>G p.S177W | Missense Mutation (SNP) | VAF 17/140 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV68776695, COSV68776780; called by muse, mutect2, varscan2
- EIF4G3 | c.2871G>C p.E957D | Missense Mutation (SNP) | VAF 6/80 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0.173); catalogued as COSV51677109, COSV51678965; called by muse, mutect2
- EIF4G3 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 47/196 reads (24%) | catalogued as COSV51677124; called by muse, mutect2, varscan2
- EIF4G3 | c.1594G>A p.E532K | Missense Mutation (SNP) | VAF 37/150 reads (25%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.099); catalogued as COSV51677147; called by muse, mutect2, varscan2
- EML5 | c.2416G>A p.G806R | Missense Mutation (SNP) | VAF 16/70 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100715694, COSV61343133; called by muse, mutect2, varscan2
- ERCC6L | c.1808C>G p.S603* | Nonsense Mutation (SNP) | VAF 12/165 reads (7%) | catalogued as COSV57819836; called by muse, mutect2
- FAM171A1 | c.1447G>A p.D483N | Missense Mutation (SNP) | VAF 23/223 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV65314419, COSV65316526; called by muse, mutect2, varscan2
- FANCM | c.2242C>G p.Q748E | Missense Mutation (SNP) | VAF 49/83 reads (59%) | SIFT tolerated (0.21); PolyPhen benign (0.033); catalogued as COSV57498466; called by muse, mutect2, varscan2
- FLACC1 | c.856G>C p.E286Q | Missense Mutation (SNP) | VAF 49/245 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.9); catalogued as COSV53782727; called by muse, mutect2, varscan2
- FLG | c.6086C>G p.S2029C | Missense Mutation (SNP) | VAF 496/1114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as COSV64238652; called by muse, mutect2, varscan2
- FLRT2 | c.889G>C p.D297H | Missense Mutation (SNP) | VAF 51/361 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.933); catalogued as COSV58138170; called by muse, mutect2, varscan2
- FRMD1 | c.1584G>C p.K528N | Missense Mutation (SNP) | VAF 6/8 reads (75%) | SIFT deleterious (0.05); PolyPhen benign (0.02); catalogued as COSV51960674; called by muse, mutect2
- FRMPD1 | c.721G>A p.E241K | Missense Mutation (SNP) | VAF 31/40 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100899465, COSV66699559; called by muse, mutect2, varscan2
- FSIP2 | c.19969A>T p.I6657L | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV58081239; called by muse, mutect2, varscan2
- GALP | c.293G>C p.G98A | Missense Mutation (SNP) | VAF 28/85 reads (33%) | SIFT tolerated, low confidence (0.38); PolyPhen benign (0.022); catalogued as COSV61999405; called by muse, varscan2
- GRIA1 | c.1339G>C p.A447P | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV53594028; called by muse, mutect2, varscan2
- HDAC10 | c.754G>C p.E252Q | Missense Mutation (SNP) | VAF 8/17 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.856); catalogued as COSV50538844; called by muse, mutect2, varscan2
- HOPX | c.167C>T p.A56V (on ENST00000317745; = p.A74V on NM_032495.6) | Missense Mutation (SNP) | VAF 56/130 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV100497068; called by muse, mutect2, varscan2
- HTR3A | c.704A>G p.Y235C | Missense Mutation (SNP) | VAF 74/116 reads (64%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.932); catalogued as rs766819242, COSV55468531; called by muse, mutect2, varscan2
- HUWE1 | c.2197G>A p.E733K | Missense Mutation (SNP) | VAF 110/303 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.755); catalogued as COSV53338654; called by muse, mutect2, varscan2
- HYDIN | c.11650G>A p.E3884K | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT tolerated (0.51); PolyPhen benign (0.123); catalogued as rs774590218, COSV66637961; called by muse, mutect2, varscan2
- IKZF3 | c.272G>A p.R91K | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT tolerated (0.21); PolyPhen benign (0.323); catalogued as COSV53100614; called by muse, mutect2, varscan2
- INO80 | c.415G>T p.D139Y | Missense Mutation (SNP) | VAF 18/39 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.552); catalogued as COSV62736810; called by muse, varscan2
- INPP5B | c.2944C>G p.Q982E (on ENST00000373023; = p.Q902E on NM_005540.3 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT tolerated (0.48); PolyPhen possibly damaging (0.505); catalogued as rs768065842, COSV65959898; called by muse, mutect2, varscan2
- IPO7 | c.1714G>A p.E572K | Missense Mutation (SNP) | VAF 13/25 reads (52%) | SIFT deleterious (0.05); PolyPhen benign (0.222); catalogued as COSV63352588; called by muse, mutect2, varscan2
- KALRN | c.1851G>C p.K617N | Missense Mutation (SNP) | VAF 34/72 reads (47%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.996); catalogued as COSV53756512; called by muse, mutect2, varscan2
- KCNT1 | c.82G>C p.E28Q | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.105); catalogued as COSV53680974; called by muse, mutect2, varscan2
- KIF19 | c.267C>G p.I89M | Missense Mutation (SNP) | VAF 37/74 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV63429068, COSV63430732; called by muse, mutect2, varscan2
- KIF1A | c.4408A>G p.T1470A (on ENST00000320389 / NM_001379639.1; = p.T1462A on NM_004321.8 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 8/11 reads (73%) | SIFT tolerated (0.17); PolyPhen benign (0.042); catalogued as COSV57485145; called by muse, mutect2, varscan2
- KIF1B | c.4829C>T p.S1610F (on ENST00000377086 / NM_001365952.1; = p.S1564F on NM_015074.3) | Missense Mutation (SNP) | VAF 36/153 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.288); catalogued as rs1482433720, COSV55805125; called by muse, varscan2
- LLPH | c.133C>T p.Q45* | Nonsense Mutation (SNP) | VAF 29/188 reads (15%) | catalogued as COSV56981470; called by muse, mutect2, varscan2
- LPXN | c.974G>A p.R325Q | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.089); catalogued as rs748289534, COSV67716540, COSV67718398; called by mutect2, varscan2
- MAGI2 | c.1897G>C p.D633H | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as rs747328733, COSV62640947; called by muse, mutect2
- MAOB | c.637G>A p.G213R | Missense Mutation (SNP) | VAF 42/109 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65204664; called by muse, mutect2, varscan2
- MAP1B | c.6446C>G p.S2149* | Nonsense Mutation (SNP) | VAF 8/65 reads (12%) | catalogued as COSV57095710, COSV99702885; called by muse, mutect2, varscan2
- MARK3 | c.760G>C p.D254H | Missense Mutation (SNP) | VAF 8/49 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53507871; called by muse, varscan2
- MCM5 | c.793A>G p.I265V | Missense Mutation (SNP) | VAF 49/156 reads (31%) | SIFT tolerated (0.77); PolyPhen benign (0.009); catalogued as rs903289977, COSV53345429; called by muse, mutect2, varscan2
- MDH1 | c.428C>G p.S143* | Nonsense Mutation (SNP) | VAF 9/87 reads (10%) | catalogued as COSV51862766; called by muse, mutect2, varscan2
- MIB1 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 13/216 reads (6%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.959); catalogued as COSV55088731, COSV55089049; called by muse, mutect2
- MKI67 | c.1834G>A p.E612K | Missense Mutation (SNP) | VAF 11/76 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.101); catalogued as COSV64073254; called by muse, mutect2, varscan2
- MSTN | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 31/61 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV53620576; called by muse, mutect2, varscan2
- MTG1 | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 15/232 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.365); catalogued as COSV53371581, COSV99529715; called by muse, mutect2
- MTMR2 | c.98C>T p.S33L | Missense Mutation (SNP) | VAF 7/18 reads (39%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.879); catalogued as COSV60578918; called by muse, mutect2, varscan2
- MYH9 | c.2893G>C p.E965Q | Missense Mutation (SNP) | VAF 41/96 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.938); catalogued as COSV53383447; called by muse, mutect2, varscan2
- NCCRP1 | c.796G>A p.D266N | Missense Mutation (SNP) | VAF 53/269 reads (20%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.812); catalogued as rs779986852, COSV59212346; called by muse, varscan2
- OLFM4 | c.1432G>C p.V478L | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as COSV54576323; called by muse, varscan2
- OR9G1 | c.253A>G p.I85V | Missense Mutation (SNP) | VAF 20/165 reads (12%) | SIFT tolerated (0.5); PolyPhen benign (0.005); catalogued as rs772571640, COSV56449306; called by muse, mutect2, varscan2
- OXSM | c.666del p.F222Lfs*2 | Frame Shift Del (DEL) | VAF 65/169 reads (38%) | catalogued as rs1381184096; called by mutect2, pindel, varscan2
- PAPLN | c.1124C>T p.S375L (on ENST00000554301; = p.S348L on NM_173462.4) | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53714981; called by muse, mutect2, varscan2
- PCM1 | c.6066G>C p.Q2022H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as rs1398957058, COSV59585808; called by muse, mutect2, varscan2
- PDE6B | c.109G>A p.E37K | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.62); PolyPhen benign (0); catalogued as rs376908835; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PHKA1 | c.782C>T p.S261L | Missense Mutation (SNP) | VAF 43/84 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as rs782692869, COSV59803531; called by muse, mutect2, varscan2
- PHTF2 | c.765C>G p.F255L (on ENST00000248550 / NM_001366089.1; = p.F217L on NM_020432.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 7/47 reads (15%) | SIFT tolerated (0.71); PolyPhen benign (0.03); catalogued as COSV50324419; called by muse, mutect2
- PLK4 | c.2170G>C p.E724Q | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54636771; called by muse, mutect2, varscan2
- POGZ | c.4124C>T p.P1375L | Missense Mutation (SNP) | VAF 41/173 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV51850784; called by muse, mutect2, varscan2
- PPARGC1A | c.631C>A p.L211I | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT tolerated (0.18); PolyPhen probably damaging (0.978); catalogued as COSV53525654; called by muse, mutect2, varscan2
- PRC1 | c.709G>A p.E237K | Missense Mutation (SNP) | VAF 15/119 reads (13%) | SIFT tolerated (0.39); PolyPhen possibly damaging (0.83); catalogued as COSV62694244, COSV62694509; called by muse, mutect2, varscan2
- PRPF8 | c.211C>G p.R71G | Missense Mutation (SNP) | VAF 5/79 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.476); catalogued as rs965356265, COSV59261572; called by muse, mutect2
- PTPN1 | c.691T>G p.C231G | Missense Mutation (SNP) | VAF 15/51 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65407573; called by muse, mutect2, varscan2
- PYHIN1 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 47/95 reads (49%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.007); catalogued as COSV63730311, COSV63731131; called by muse, mutect2, varscan2
- RAG2 | c.823G>A p.G275S | Missense Mutation (SNP) | VAF 19/39 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57556866; called by muse, mutect2, varscan2
- RARG | c.809T>C p.I270T | Missense Mutation (SNP) | VAF 141/366 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58432214; called by muse, mutect2, varscan2
- RP1L1 | c.2735G>A p.S912N | Missense Mutation (SNP) | VAF 5/16 reads (31%) | SIFT tolerated (0.28); PolyPhen possibly damaging (0.462); catalogued as COSV101223631, COSV66751685; called by muse, mutect2
- SBDS | c.619G>C p.E207Q | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.384); catalogued as COSV55887252; called by muse, mutect2, varscan2
- SEMA3F | c.1132G>C p.D378H | Missense Mutation (SNP) | VAF 7/62 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV50028684, COSV99137982; called by muse, mutect2, varscan2
- SERPIND1 | c.1169G>A p.R390Q | Missense Mutation (SNP) | VAF 20/170 reads (12%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.966); catalogued as rs368023291; called by muse, varscan2
- SLC2A13 | c.809G>A p.G270E | Missense Mutation (SNP) | VAF 33/165 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.838); catalogued as rs766389341, COSV55113246; called by muse, mutect2, varscan2
- SLC8A3 | c.1153G>A p.E385K | Missense Mutation (SNP) | VAF 77/129 reads (60%) | SIFT tolerated (0.05); PolyPhen benign (0.228); catalogued as rs1438650441, COSV63519269; called by muse, mutect2, varscan2
- SOS1 | c.581C>T p.S194F | Missense Mutation (SNP) | VAF 61/152 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.013); catalogued as COSV67674339; called by muse, mutect2, varscan2
- SPATS2 | c.1089G>C p.K363N | Missense Mutation (SNP) | VAF 33/73 reads (45%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.614); catalogued as COSV58917425; called by muse, mutect2, varscan2
- SRCAP | c.7802C>G p.S2601C | Missense Mutation (SNP) | VAF 24/77 reads (31%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.319); catalogued as COSV52669296; called by muse, mutect2, varscan2
- ST7L | c.997G>A p.E333K | Missense Mutation (SNP) | VAF 33/119 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58307736; called by muse, mutect2, varscan2
- STAG2 | c.2308C>T p.Q770* | Nonsense Mutation (SNP) | VAF 50/160 reads (31%) | catalogued as COSV54353721; called by muse, mutect2, varscan2
- SYNE1 | c.20318G>A p.G6773E (on ENST00000367255 / NM_182961.4; = p.G6702E on NM_033071.3) | Missense Mutation (SNP) | VAF 52/75 reads (69%) | SIFT tolerated (0.18); PolyPhen probably damaging (1); catalogued as COSV54932936; called by muse, mutect2, varscan2
- SYNE1 | c.20005C>G p.Q6669E (on ENST00000367255 / NM_182961.4; = p.Q6598E on NM_033071.3) | Missense Mutation (SNP) | VAF 43/56 reads (77%) | SIFT tolerated (0.61); PolyPhen benign (0.017); catalogued as COSV54932986; called by muse, mutect2, varscan2
- SYNE1 | c.6463G>A p.E2155K (on ENST00000367255 / NM_182961.4; = p.E2162K on NM_033071.3) | Missense Mutation (SNP) | VAF 42/50 reads (84%) | SIFT deleterious (0); PolyPhen possibly damaging (0.678); catalogued as COSV54933017; called by muse, mutect2, varscan2
- TAF4B | c.1136C>T p.S379L | Missense Mutation (SNP) | VAF 59/73 reads (81%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV52302166; called by muse, mutect2, varscan2
- TENM1 | c.2486A>T p.Y829F | Missense Mutation (SNP) | VAF 100/174 reads (57%) | SIFT tolerated (0.4); PolyPhen benign (0.001); catalogued as COSV64427554; called by muse, mutect2, varscan2
- TFR2 | c.8G>A p.R3Q | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0); catalogued as rs1455682946, COSV50514061; called by muse, mutect2, varscan2
- TG | c.4825G>A p.E1609K | Missense Mutation (SNP) | VAF 12/104 reads (12%) | SIFT tolerated (0.92); PolyPhen benign (0); catalogued as COSV55069438, COSV55096848; called by muse, varscan2
- TJAP1 | c.126G>T p.M42I | Missense Mutation (SNP) | VAF 54/73 reads (74%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.946); catalogued as COSV52499818; called by muse, mutect2, varscan2
- TRPM3 | c.4762C>G p.P1588A (on ENST00000357533 / NM_001366142.2; = p.P1443A on NM_020952.6) | Missense Mutation (SNP) | VAF 57/83 reads (69%) | SIFT tolerated, low confidence (0.27); PolyPhen probably damaging (0.991); catalogued as COSV62582169; called by muse, mutect2, varscan2
- TRPM7 | c.1525C>G p.L509V | Missense Mutation (SNP) | VAF 21/45 reads (47%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.656); catalogued as COSV57914700; called by muse, mutect2, varscan2
- TRPV2 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 13/37 reads (35%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as rs760893358, COSV58427704, COSV58429822; called by muse, mutect2, varscan2
- TRUB1 | c.832A>G p.T278A | Missense Mutation (SNP) | VAF 24/101 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.906); catalogued as COSV53928693; called by muse, varscan2
- TTC14 | c.1084G>C p.E362Q | Missense Mutation (SNP) | VAF 109/194 reads (56%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.575); catalogued as COSV56010033, COSV99931989; called by muse, mutect2, varscan2
- UBTF | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57185339; called by muse, mutect2, varscan2
- USP29 | c.1144G>C p.D382H | Missense Mutation (SNP) | VAF 40/96 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54140890; called by muse, mutect2, varscan2
- VCAN | c.208G>T p.E70* | Nonsense Mutation (SNP) | VAF 22/91 reads (24%) | catalogued as COSV54099884; called by muse, mutect2, varscan2
- VWF | c.1616C>G p.S539C | Missense Mutation (SNP) | VAF 30/94 reads (32%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV54614611; called by muse, varscan2
- YAP1 | c.1021C>G p.P341A | Missense Mutation (SNP) | VAF 52/99 reads (53%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.98); catalogued as COSV56772868; called by muse, mutect2, varscan2
- YAP1 | c.1188G>C p.E396D (on ENST00000282441 / NM_001130145.3; = p.E342D on NM_006106.5) | Missense Mutation (SNP) | VAF 11/40 reads (28%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.82); catalogued as COSV56772875; called by muse, varscan2
- ZFYVE19 | c.187G>A p.D63N | Missense Mutation (SNP) | VAF 16/27 reads (59%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as COSV54539591; called by muse, varscan2
- ZFYVE19 | c.228G>A p.M76I | Missense Mutation (SNP) | VAF 10/35 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV54539604; called by muse, varscan2
- ZNF347 | c.2206C>A p.P736T | Missense Mutation (SNP) | VAF 26/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV61967944; called by muse, mutect2, varscan2
- ZNF689 | c.529T>C p.Y177H | Missense Mutation (SNP) | VAF 17/66 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.094); catalogued as COSV54908058; called by muse, mutect2, varscan2
- ZZEF1 | c.7129C>G p.Q2377E | Missense Mutation (SNP) | VAF 11/36 reads (31%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV67556382; called by muse, mutect2, varscan2
- BMP8A | c.1183del p.V395Wfs*33 | Frame Shift Del (DEL) | VAF 29/162 reads (18%) | called by mutect2, pindel, varscan2
- CNGA3 | c.888_889insGT p.Y297Vfs*66 | Frame Shift Ins (INS) | VAF 18/89 reads (20%) | called by mutect2, pindel, varscan2
- KANSL1 | c.536del p.G179Efs*23 | Frame Shift Del (DEL) | VAF 103/284 reads (36%) | called by mutect2, pindel, varscan2
- KDM6A | c.4129_4130del p.Q1377Vfs*11 | Frame Shift Del (DEL) | VAF 30/100 reads (30%) | called by mutect2, pindel, varscan2
- MPRIP | c.987del p.S329Rfs*54 | Frame Shift Del (DEL) | VAF 14/55 reads (25%) | called by mutect2, pindel, varscan2
- TXNIP | c.493_495del p.E165del | In Frame Del (DEL) | VAF 332/603 reads (55%) | called by mutect2, pindel, varscan2
- AHNAK2 | c.12066C>T p.S4022= | Silent (SNP) | VAF 79/113 reads (70%) | catalogued as rs372712364, COSV60910675; called by muse, mutect2, varscan2
- AKAP13 | c.6765C>G p.L2255= (on ENST00000394518 / NM_007200.5; = p.L2259= on NM_006738.6) | Silent (SNP) | VAF 28/117 reads (24%) | catalogued as COSV63451596; called by muse, mutect2, varscan2
- ANK3 | c.10506C>T p.F3502= | Silent (SNP) | VAF 13/58 reads (22%) | catalogued as COSV55049095; called by muse, mutect2, varscan2
- ATG9B | c.723C>T p.L241= | Silent (SNP) | VAF 60/331 reads (18%) | catalogued as COSV65057492; called by muse, mutect2, varscan2
- CDC42 | c.357C>G p.L119= | Silent (SNP) | VAF 65/259 reads (25%) | catalogued as COSV59661596; called by muse, mutect2, varscan2
- CDC42 | c.456C>G p.V152= | Silent (SNP) | VAF 53/221 reads (24%) | catalogued as COSV59661616; called by muse, mutect2, varscan2
- CHD6 | c.7614C>T p.L2538= | Silent (SNP) | VAF 20/139 reads (14%) | catalogued as COSV64688999; called by muse, mutect2, varscan2
- CIDEB | c.477C>G p.L159= | Silent (SNP) | VAF 22/96 reads (23%) | catalogued as rs780437046, COSV51865052; called by muse, mutect2, varscan2
- DEPP1 | c.597C>T p.L199= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV53573631; called by muse, mutect2, varscan2
- DRAXIN | c.915C>T p.F305= | Silent (SNP) | VAF 24/142 reads (17%) | catalogued as rs753503038, COSV53842216; called by muse, mutect2, varscan2
- EIF4A3 | c.36G>C p.S12= | Silent (SNP) | VAF 7/36 reads (19%) | catalogued as COSV53919901, COSV99483930; called by muse, mutect2, varscan2
- FGA | c.1989C>T p.C663= | Silent (SNP) | VAF 13/44 reads (30%) | catalogued as rs142544370; called by muse, mutect2, varscan2
- HAP1 | c.1014C>T p.L338= | Silent (SNP) | VAF 56/90 reads (62%) | catalogued as rs782353223, COSV57877793; called by muse, mutect2, varscan2
- HLA-B | c.180C>T p.F60= | Silent (SNP) | VAF 27/36 reads (75%) | catalogued as rs151341114, COSV101317991, COSV69520759; called by muse, mutect2, varscan2
- HRH4 | c.273C>T p.L91= | Silent (SNP) | VAF 12/102 reads (12%) | catalogued as COSV56927631; called by muse, mutect2, varscan2
- INPP5B | c.2281C>T p.L761= (on ENST00000373023; = p.L681= on NM_005540.3 and 3 other RefSeq transcripts) | Silent (SNP) | VAF 30/172 reads (17%) | catalogued as COSV65959901; called by muse, mutect2, varscan2
- KLK10 | c.585C>A p.I195= | Silent (SNP) | VAF 62/355 reads (17%) | catalogued as COSV59397625; called by muse, mutect2, varscan2
- MATN2 | c.1464C>T p.C488= | Silent (SNP) | VAF 25/64 reads (39%) | catalogued as COSV54708309; called by muse, mutect2, varscan2
- NLRP7 | c.1344C>T p.F448= | Silent (SNP) | VAF 6/42 reads (14%) | catalogued as COSV60172161; called by muse, mutect2, varscan2
- OR10Z1 | c.75C>T p.L25= | Silent (SNP) | VAF 31/219 reads (14%) | catalogued as COSV63524173; called by muse, mutect2, varscan2
- OR2L8 | c.426G>A p.L142= | Silent (SNP) | VAF 24/258 reads (9%) | catalogued as rs761587541, COSV61726003; called by muse, mutect2
- OR51G2 | c.621C>T p.V207= | Silent (SNP) | VAF 11/26 reads (42%) | catalogued as COSV58992174; called by muse, mutect2, varscan2
- OR6N1 | c.663C>T p.I221= | Silent (SNP) | VAF 107/208 reads (51%) | catalogued as COSV58647705; called by muse, mutect2, varscan2
- P2RX4 | c.39C>T p.F13= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV58742203; called by muse, mutect2, varscan2
- PCDHGC3 | c.1227G>A p.L409= | Silent (SNP) | VAF 12/57 reads (21%) | catalogued as COSV52746690; called by muse, mutect2, varscan2
- PCSK7 | c.666G>T p.V222= | Silent (SNP) | VAF 38/127 reads (30%) | catalogued as COSV58006284; called by muse, mutect2, varscan2
- PEX10 | c.189T>G p.L63= | Silent (SNP) | VAF 24/54 reads (44%) | catalogued as COSV56579800; called by muse, mutect2, varscan2
- PGRMC1 | c.171C>T p.S57= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as COSV54292058; called by mutect2, varscan2
- PRF1 | c.375C>T p.I125= | Silent (SNP) | VAF 6/37 reads (16%) | catalogued as COSV100942654; called by muse, mutect2, varscan2
- PTPRF | c.1869C>T p.V623= | Silent (SNP) | VAF 14/25 reads (56%) | catalogued as COSV63443649; called by muse, varscan2
- PTPRF | c.1917C>T p.I639= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as COSV63443654; called by muse, varscan2
- RBM26 | c.582G>A p.E194= | Silent (SNP) | VAF 42/303 reads (14%) | catalogued as rs199797508, COSV57392564; called by muse, mutect2, varscan2
- SERPIND1 | c.1200G>A p.E400= | Silent (SNP) | VAF 23/180 reads (13%) | catalogued as COSV53137872; called by muse, varscan2
- SGCD | c.780C>T p.F260= (on ENST00000435422 / NM_001128209.2; = p.F261= on NM_000337.5) | Silent (SNP) | VAF 42/121 reads (35%) | catalogued as rs768741617, COSV61903980, COSV61905794; called by muse, mutect2, varscan2
- TAS2R41 | c.855C>T p.F285= | Silent (SNP) | VAF 14/79 reads (18%) | catalogued as rs750163018, COSV68765049; called by mutect2, varscan2
- TMEM74B | c.702G>A p.G234= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV67891754; called by muse, mutect2
- FGFR3 | c.*1231G>A | 3'UTR (SNP) | VAF 10/12 reads (83%) | catalogued as rs377402598; called by mutect2, varscan2
- MYADM | chr19:53874298 C>T | 3'Flank (SNP) | VAF 19/95 reads (20%) | catalogued as rs1292421786, COSV61238760; called by muse, mutect2, varscan2
